Somatic mutation profile of tumor specimen 0DA8LH from CCDI case PBBJPU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.4 years (2,719 days).
Specimen 0DA8LH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25813392-b4bf-434d-8bca-de46311391c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DA8L8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e448754e-51f1-4b94-a6dd-a707bb5c5688

The open-access MAF lists 13 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 5, Silent 4, Missense Mutation 2, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.4277C>T p.A1426V | Missense Mutation (SNP) | VAF 154/592 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs144560370, COSV100710045; called by muse, mutect2, varscan2
- KIF13B | c.5284G>A p.V1762I | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1308777903; called by muse, mutect2, varscan2
- MACROD2 | c.1315+1G>C p.X439_splice (on ENST00000642719; = p.X411_splice on NM_080676.6 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 128/572 reads (22%) | catalogued as COSV99428558; called by muse, mutect2, varscan2
- CDC42BPG | c.4572G>A p.S1524= | Silent (SNP) | VAF 23/350 reads (7%) | catalogued as rs768281378; called by muse, mutect2
- HDAC3 | c.660C>T p.N220= | Silent (SNP) | VAF 72/264 reads (27%) | catalogued as rs141006049; called by muse, mutect2, varscan2
- IRS2 | c.3039G>A p.P1013= | Silent (SNP) | VAF 99/221 reads (45%) | catalogued as rs751368642; called by muse, mutect2, varscan2
- SLC38A3 | c.903C>T p.P301= | Silent (SNP) | VAF 119/307 reads (39%) | catalogued as rs764097413; called by muse, mutect2, varscan2
- APOC2 | c.215+49C>A | Intron (SNP) | VAF 6/107 reads (6%) | called by muse, mutect2
- GCFC2 | c.1145-91T>A | Intron (SNP) | VAF 4/33 reads (12%) | called by muse, varscan2
- GCFC2 | c.1145-92T>A | Intron (SNP) | VAF 4/33 reads (12%) | called by muse, varscan2
- NBEAL2 | c.2557-33A>G | Intron (SNP) | VAF 48/101 reads (48%) | called by muse, mutect2, varscan2
- NISCH | c.1528+672G>A | Intron (SNP) | VAF 80/156 reads (51%) | catalogued as rs948001788; called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 22/180 reads (12%) | called by muse, varscan2
